MMRF case MMRF_2437 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7de1d5bd-04a8-4170-be09-5459affd2f57

Demographics
Sex at birth: female; Race: asian; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.6 years (26,139 days); ISS stage: II; Days to last known disease status: 766 days (2.1 years); Days to last follow up: 766 days (2.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 53 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 8 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 57 days.
   Treatment given: Therapeutic agents: Dexamethasone + Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 106 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 107 days; Days to treatment end: 107 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 0): M Protein 3.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 73.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 59.2 g/L; Immunoglobulin A 1.28 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 3.7 µg/mL; Lactate Dehydrogenase 1.6 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 276 ×10⁹/L; Creatinine 91.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 31 g/L; Total Protein 10.6 g/dL; Glucose 4.95 mmol/L.
- Day 106 (ECOG 1): M Protein 0.26 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.07 mg/dL; Immunoglobulin G 16.2 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.61 g/L; Lactate Dehydrogenase 6.75 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 20.6 ×10⁹/L; Absolute Neutrophil 20.2 ×10⁹/L; Platelets 323 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 7.8 g/dL; Glucose 5.28 mmol/L.
- Day 175 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.75 mg/dL; Immunoglobulin G 14.8 g/L; Immunoglobulin A 1.37 g/L; Immunoglobulin M 0.79 g/L; Lactate Dehydrogenase 3.65 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 259 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 7.2 g/dL; Glucose 4.9 mmol/L.
- Day 294 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.12 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 0.99 g/L; Immunoglobulin M 0.77 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.58 mmol/L; Albumin 47 g/L; Total Protein 7.6 g/dL; Glucose 6.27 mmol/L.
- Day 385 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.24 mg/dL; Immunoglobulin G 13.7 g/L; Immunoglobulin A 1.48 g/L; Immunoglobulin M 1.24 g/L; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 270 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.5 mmol/L; Albumin 46 g/L; Total Protein 7.6 g/dL; Glucose 4.62 mmol/L.
- Day 476 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 14.5 g/L; Immunoglobulin A 1.5 g/L; Immunoglobulin M 0.75 g/L; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 7.5 g/dL; Glucose 5.17 mmol/L.
- Day 567 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Immunoglobulin G 17.1 g/L; Immunoglobulin A 2.37 g/L; Immunoglobulin M 0.73 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 227 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 7.7 g/dL; Glucose 3.96 mmol/L.
- Day 668 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.72 mg/dL; Immunoglobulin G 17 g/L; Immunoglobulin A 2.4 g/L; Immunoglobulin M 0.77 g/L; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7.7 g/dL; Glucose 5.01 mmol/L.
- Day 766 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.99 mg/dL; Immunoglobulin G 14.5 g/L; Immunoglobulin A 2.33 g/L; Immunoglobulin M 0.79 g/L; Lactate Dehydrogenase 2.72 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.21 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 43 g/L; Total Protein 7.8 g/dL; Glucose 5.17 mmol/L.

Other clinical attributes
- Day -3: Weight: 53 kg; Height: 149 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2437_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_2437_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
